Somatic mutation profile of tumor specimen TCGA-13-0760-01A (aliquot TCGA-13-0760-01A-01W-0371-08) from TCGA case TCGA-13-0760, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 63.1 years (23,036 days).
Specimen TCGA-13-0760-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca31f7cf-3b41-4dc7-b0b4-1e705124afe3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0760-10A (Blood Derived Normal), aliquot TCGA-13-0760-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/123a2ba2-0053-402e-8642-5f79e7ca71c8

The open-access MAF lists 193 somatic variants for this specimen: 149 protein-altering or splice-affecting, 38 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 38, Nonsense Mutation 9, In Frame Del 5, Frame Shift Del 5, Intron 4, Splice Site 3, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.794T>C p.L265P | Missense Mutation (SNP) | VAF 34/42 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879253942, CD004355, CM971505, COSV52706540, COSV52732531, COSV53696163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.1729C>G p.H577D | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV65411213; called by muse, mutect2, varscan2
- ALB | c.521A>T p.Y174F | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV55740756; called by muse, mutect2, varscan2
- AR | c.2185T>A p.L729I | Missense Mutation (SNP) | VAF 392/602 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65961566; called by muse, mutect2, varscan2
- ARHGAP21 | c.2387C>A p.P796Q | Missense Mutation (SNP) | VAF 229/588 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57609579; called by muse, mutect2, varscan2
- ARHGEF9 | c.576G>T p.W192C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV53642064; called by muse, mutect2
- ARID1A | c.5122C>T p.Q1708* | Nonsense Mutation (SNP) | VAF 52/160 reads (33%) | catalogued as COSV61380903; called by muse, mutect2, varscan2
- ATR | c.6167A>T p.N2056I | Missense Mutation (SNP) | VAF 71/500 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV63389684; called by muse, mutect2, varscan2
- BAG3 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs375650805; called by muse, mutect2, varscan2
- BICDL1 | c.1309-1G>C p.X437_splice | Splice Site (SNP) | VAF 19/42 reads (45%) | catalogued as COSV57494178; called by muse, mutect2, varscan2
- BPI | c.860T>C p.L287P (on ENST00000262865; = p.L283P on NM_001725.3) | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53407334; called by muse, mutect2, varscan2
- BRINP2 | c.2266G>A p.V756M | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as rs766709306, COSV100838515, COSV64179256; called by muse, mutect2, varscan2
- C2CD2 | c.1127G>C p.G376A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61600178, COSV61600402; called by mutect2, varscan2
- CACNA1A | c.3486G>C p.K1162N | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.798); catalogued as COSV64206938; called by muse, mutect2, varscan2
- CACNA1C | c.212C>A p.A71E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV100217680, COSV59753819; called by muse, mutect2
- CACNB3 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); catalogued as rs1240347346, COSV99974573; called by muse, mutect2
- CALR3 | c.232T>A p.S78T | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99522010; called by muse, mutect2
- CAMK2B | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs769713153, COSV51664221; called by muse, mutect2, varscan2
- CAPN5 | c.1548G>C p.E516D (on ENST00000456580; = p.E476D on NM_004055.5) | Missense Mutation (SNP) | VAF 95/673 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV99581567; called by muse, mutect2, varscan2
- CCDC18 | c.1337T>G p.I446S | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV58146237; called by muse, mutect2
- CCDC62 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV53436069; called by muse, mutect2, varscan2
- CDH26 | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774165611, COSV54844695, COSV54851537; called by muse, mutect2, varscan2
- CELA2B | c.168C>G p.H56Q | Missense Mutation (SNP) | VAF 112/362 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65546067; called by muse, mutect2, varscan2
- CFAP58 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57213122, COSV57213727; called by muse, mutect2, varscan2
- CHAF1B | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58439294, COSV58441094; called by muse, mutect2, varscan2
- CHD8 | c.3275G>A p.R1092H (on ENST00000646647 / NM_001170629.2; = p.R813H on NM_020920.4) | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1215755967, COSV67872030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIP2A | c.1884G>A p.M628I | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV99842525; called by muse, mutect2
- CLEC4D | c.460T>G p.W154G | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100222817; called by muse, mutect2, varscan2
- CLEC4D | c.461G>T p.W154L | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100222821, COSV55228125; called by muse, mutect2, varscan2
- CLEC4F | c.279C>A p.H93Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV55480657; called by muse, mutect2, varscan2
- CMTM2 | c.470G>C p.C157S | Missense Mutation (SNP) | VAF 104/249 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV51749374; called by muse, mutect2, varscan2
- CNGA1 | c.1044_1055delinsTA p.L349Ifs*3 | Frame Shift Del (DEL) | VAF 32/195 reads (16%) | catalogued as COSV62055876; called by pindel, varscan2*
- CNN1 | c.882C>A p.Y294* | Nonsense Mutation (SNP) | VAF 38/1434 reads (3%) | catalogued as COSV99370547; called by muse, mutect2
- CNOT1 | c.2342T>C p.L781P | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV57776833; called by muse, mutect2, varscan2
- COL11A1 | c.4984T>A p.S1662T | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); catalogued as COSV62191163; called by muse, mutect2, varscan2
- CPZ | c.1069G>T p.V357L (on ENST00000360986 / NM_001014447.3; = p.V346L on NM_003652.3) | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as COSV59924698; called by muse, mutect2, varscan2
- CSMD3 | c.7535T>A p.L2512H (on ENST00000297405 / NM_001363185.1; = p.L2408H on NM_052900.3) | Missense Mutation (SNP) | VAF 87/203 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52266417, COSV52340017, COSV99847242; called by muse, mutect2, varscan2
- CYP2C19 | c.1334T>A p.L445Q | Missense Mutation (SNP) | VAF 228/558 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64908773; called by muse, mutect2, varscan2
- DCLK3 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 96/408 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs776262039, COSV69364173; called by muse, mutect2, varscan2
- DNAH10 | c.2727C>A p.H909Q (on ENST00000409039; = p.H848Q on NM_207437.3) | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV68998654; called by muse, mutect2, varscan2
- DQX1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV66353400, COSV66353519; called by muse, mutect2, varscan2
- DST | c.15193A>G p.K5065E (on ENST00000361203 / NM_001374722.1; = p.K2653E on NM_015548.5) | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV55031096; called by muse, mutect2, varscan2
- DST | c.3044G>A p.R1015H (on ENST00000361203 / NM_001374722.1; = p.R689H on NM_001723.6) | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1003908769, COSV55025131; called by muse, mutect2, varscan2
- DYNC1I1 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV61467566, COSV61468297; called by muse, mutect2, varscan2
- EIF3K | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV50264422; called by muse, mutect2, varscan2
- EOMES | c.1837G>T p.E613* | Nonsense Mutation (SNP) | VAF 63/127 reads (50%) | catalogued as COSV55414476; called by muse, mutect2, varscan2
- ERMARD | c.1843C>G p.Q615E | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV100824508; called by muse, mutect2, varscan2
- F5 | c.6446A>G p.Y2149C | Missense Mutation (SNP) | VAF 103/375 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63126419; called by muse, mutect2, varscan2
- FAM98A | c.230T>A p.L77H | Missense Mutation (SNP) | VAF 162/714 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1553372834, COSV53211348; called by muse, mutect2, varscan2
- FCRL6 | c.1168G>C p.V390L | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs748053161, COSV58942050, COSV58943142; called by muse, mutect2, varscan2
- FIP1L1 | c.493T>A p.W165R | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60998709; called by muse, mutect2, varscan2
- GOLGB1 | c.3795A>T p.E1265D | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61468986; called by muse, mutect2, varscan2
- GPR119 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV52276298; called by muse, mutect2, varscan2
- HEXD | c.382G>C p.A128P | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV60065275; called by muse, mutect2, varscan2
- IGLV10-54 | c.99G>T p.L33F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.827); catalogued as COSV66505020; called by muse, mutect2, varscan2
- ING2 | c.759G>T p.W253C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100180407, COSV56564480; called by muse, mutect2, varscan2
- KCNH1 | c.1032G>T p.Q344H | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55094687; called by muse, mutect2, varscan2
- KDM2A | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1184539129, COSV58190786; called by muse, mutect2, varscan2
- KIAA2026 | c.917C>G p.A306G | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV67354097, COSV67356800; called by muse, mutect2, varscan2
- KIF3B | c.1520G>C p.R507T | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.298); catalogued as COSV65228745; called by muse, mutect2, varscan2
- KIR3DL3 | c.604T>A p.L202I | Missense Mutation (SNP) | VAF 517/1885 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV52550061; called by muse, mutect2, varscan2
- KLHL4 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64139911; called by muse, mutect2, varscan2
- KMT5B | c.2283G>T p.K761N | Missense Mutation (SNP) | VAF 201/520 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58568650; called by muse, mutect2, varscan2
- LCE3E | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.929); catalogued as COSV64232073; called by muse, mutect2, varscan2
- LIMA1 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs780877633, COSV57967612; called by muse, mutect2, varscan2
- LRP1 | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54520303; called by muse, mutect2, varscan2
- LRRK2 | c.6466G>T p.V2156F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1555194625, COSV54163911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MIDEAS | c.1325G>C p.C442S | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.66); PolyPhen benign (0.062); catalogued as COSV54097552; called by muse, mutect2, varscan2
- MLST8 | c.935A>G p.Q312R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV57030664; called by muse, mutect2, varscan2
- NAT16 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 101/231 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV55865332; called by muse, mutect2, varscan2
- NLK | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.178); catalogued as rs750122475, COSV69410122; called by muse, mutect2, varscan2
- NOC2L | c.1693A>C p.N565H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58989996; called by muse, mutect2, varscan2
- NRDE2 | c.73T>G p.W25G | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62964238; called by muse, mutect2, varscan2
- OR5D18 | c.186T>G p.F62L | Missense Mutation (SNP) | VAF 233/881 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV100450675, COSV61738144; called by muse, mutect2, varscan2
- PAMR1 | c.2044C>T p.R682C (on ENST00000619888 / NM_001001991.3; = p.R699C on NM_015430.4) | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.438); catalogued as rs773399805, COSV53515138; called by muse, mutect2, varscan2
- PCDH17 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as rs1466552019, COSV64977183; called by muse, mutect2, varscan2
- PCSK9 | c.1211C>A p.P404Q | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.823); catalogued as COSV56163741; called by muse, mutect2, varscan2
- PDILT | c.1126T>A p.S376T | Missense Mutation (SNP) | VAF 24/525 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as COSV100198900; called by muse, mutect2
- PHKA1 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100262208; called by muse, mutect2, varscan2
- PIK3R4 | c.3281A>C p.E1094A | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV63242972; called by muse, mutect2, varscan2
- PLCB2 | c.212A>C p.K71T | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV53036419; called by muse, mutect2, varscan2
- PPP6R1 | c.1079A>T p.K360M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101336907; called by muse, mutect2, varscan2
- PSD2 | c.1589A>G p.K530R | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.292); catalogued as COSV51205939; called by muse, mutect2, varscan2
- PSMB6 | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 268/886 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54513259; called by muse, mutect2, varscan2
- PSMC3 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 1463/1867 reads (78%) | catalogued as COSV54082150; called by muse, mutect2, varscan2
- PTCHD3 | c.1876G>C p.G626R | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71257169; called by muse, mutect2, varscan2
- PTER | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54346775; called by muse, mutect2, varscan2
- PTPN13 | c.3525C>G p.I1175M (on ENST00000411767 / NM_080683.3; = p.I1156M on NM_006264.3) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs755064196, COSV57413583; called by muse, mutect2, varscan2
- PTTG1IP | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58366717; called by muse, mutect2, varscan2
- RALGDS | c.1369C>G p.P457A | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.105); catalogued as COSV100924215; called by muse, mutect2, varscan2
- RBM4 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59519828; called by muse, mutect2, varscan2
- RELA | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV100425940, COSV58015651; called by muse, mutect2, varscan2
- RHAG | c.646C>A p.L216I | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV100006200, COSV57704141; called by muse, mutect2, varscan2
- RMND5A | c.546G>C p.M182I | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV52154890; called by muse, mutect2
- RPIA | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV52171041; called by muse, mutect2, varscan2
- RYR3 | c.8651C>A p.P2884H (on ENST00000389232; = p.P2885H on NM_001036.6) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV66802913; called by muse, mutect2, varscan2
- SCIN | c.865G>A p.A289T (on ENST00000297029 / NM_001112706.3; = p.A42T on NM_033128.3) | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs776825064, COSV51696685; called by muse, mutect2, varscan2
- SEMA5B | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs148102705, COSV52104555; called by muse, mutect2, varscan2
- SEMG2 | c.296A>T p.H99L | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); catalogued as COSV101033882; called by muse, mutect2
- SERPINA10 | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 93/124 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472949765, COSV56229202; called by muse, mutect2, varscan2
- SFMBT2 | c.1453A>T p.K485* | Nonsense Mutation (SNP) | VAF 7/193 reads (4%) | catalogued as COSV100738198; called by muse, mutect2
- SIPA1L1 | c.1511A>G p.Y504C | Missense Mutation (SNP) | VAF 232/296 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62172353; called by muse, mutect2, varscan2
- SLC10A3 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54836996; called by muse, mutect2, varscan2
- SLC5A3 | c.598A>G p.M200V | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV62972181; called by muse, mutect2, varscan2
- SLC7A4 | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV100298437; called by muse, mutect2, varscan2
- SLITRK2 | c.404G>A p.S135N | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.34); catalogued as COSV59427657, COSV59428109; called by muse, mutect2, varscan2
- SLITRK6 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 229/463 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV68391120; called by muse, mutect2, varscan2
- SP110 | c.520C>G p.P174A | Missense Mutation (SNP) | VAF 145/524 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.312); catalogued as COSV51251212; called by muse, mutect2, varscan2
- SPINK5 | c.3037G>C p.V1013L | Missense Mutation (SNP) | VAF 202/451 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56259722; called by muse, mutect2, varscan2
- SPOCK1 | c.601A>C p.K201Q | Missense Mutation (SNP) | VAF 121/371 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.677); catalogued as rs1203828637, COSV56459575; called by muse, mutect2, varscan2
- SSH1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58458699; called by muse, mutect2, varscan2
- ST14 | c.1967A>C p.H656P | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53835694; called by muse, mutect2, varscan2
- STAT2 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 499/2156 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV58476650; called by muse, mutect2, varscan2
- TBC1D14 | c.844-1G>C p.X282_splice | Splice Site (SNP) | VAF 27/68 reads (40%) | catalogued as COSV63391774; called by muse, mutect2, varscan2
- THOP1 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); catalogued as COSV57020099; called by muse, mutect2, varscan2
- TLR3 | c.784A>G p.T262A | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1249967512, COSV57169734; called by muse, mutect2, varscan2
- TLR4 | c.119G>T p.C40F | Missense Mutation (SNP) | VAF 106/576 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923909; called by muse, mutect2, varscan2
- TMEM108 | c.1289T>A p.L430H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58878646; called by muse, mutect2
- TMEM63A | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 21/95 reads (22%) | catalogued as rs1275691433, COSV55302910; called by muse, mutect2, varscan2
- TMPRSS3 | c.1160C>A p.A387E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52305912; called by muse, mutect2, varscan2
- TTC17 | c.2613C>G p.Y871* | Nonsense Mutation (SNP) | VAF 42/179 reads (23%) | catalogued as COSV50014594; called by muse, mutect2, varscan2
- TTLL5 | c.2776C>T p.P926S | Missense Mutation (SNP) | VAF 304/395 reads (77%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV54040440; called by muse, mutect2, varscan2
- TTN | c.37721T>A p.V12574D (on ENST00000591111; = p.V5150D on NM_003319.4) | Missense Mutation (SNP) | VAF 126/433 reads (29%) | PolyPhen possibly damaging (0.827); catalogued as COSV60237639; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3277C>A p.L1093I | Missense Mutation (SNP) | VAF 102/319 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.505); catalogued as COSV51958779; called by muse, mutect2, varscan2
- UNC13B | c.4540G>A p.V1514M | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371689397, COSV61468723; called by muse, mutect2, varscan2
- USH2A | c.6829T>C p.Y2277H | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56409894; called by muse, mutect2, varscan2
- VEPH1 | c.920G>C p.S307T | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100747219; called by muse, mutect2
- VPS52 | c.1577C>G p.T526R | Missense Mutation (SNP) | VAF 155/508 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.641); catalogued as COSV71403579; called by muse, mutect2, varscan2
- VWA8 | c.4349C>G p.S1450C | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV64998866; called by muse, mutect2, varscan2
- WNK1 | c.2609C>T p.T870I | Missense Mutation (SNP) | VAF 110/439 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60041543; called by muse, mutect2, varscan2
- ZBTB5 | c.362C>A p.T121K | Missense Mutation (SNP) | VAF 88/409 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57041153; called by muse, mutect2, varscan2
- ZHX1 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 230/715 reads (32%) | catalogued as COSV52878176; called by muse, mutect2, varscan2
- ZNF202 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 94/117 reads (80%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV60248025; called by muse, mutect2, varscan2
- ZNF425 | c.1547A>G p.H516R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65202140; called by muse, mutect2, varscan2
- ZNF470 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV57970129; called by muse, mutect2, varscan2
- ZNF488 | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs966532272; called by muse, mutect2, varscan2
- ZNF536 | c.166C>G p.P56A | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs776167057, COSV62830554; called by muse, mutect2, varscan2
- ZNF568 | c.497C>A p.S166* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV61742473; called by muse, mutect2, varscan2
- ZNHIT1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 88/407 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs376183663, COSV100521923; called by muse, mutect2, varscan2
- ABI3 | c.652_677del p.E218Qfs*61 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2*, pindel
- ASNSD1 | c.385_423del p.H129_R141del | In Frame Del (DEL) | VAF 34/144 reads (24%) | called by mutect2, pindel
- BCLAF1 | c.2444_2446del p.T815del | In Frame Del (DEL) | VAF 16/120 reads (13%) | called by mutect2, pindel, varscan2
- HOOK1 | c.1948-13_1954del p.X650_splice | Splice Site (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- LAMA4 | c.6_22del p.S4Gfs*26 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel
- MAGI3 | c.2089_2093del p.S697Ifs*8 | Frame Shift Del (DEL) | VAF 14/126 reads (11%) | called by pindel, varscan2
- PLPP3 | c.273_281del p.G92_V94del | In Frame Del (DEL) | VAF 124/828 reads (15%) | called by mutect2, pindel, varscan2
- SPEG | c.2138_2170del p.S713_V723del | In Frame Del (DEL) | VAF 92/108 reads (85%) | called by mutect2, pindel
- TEF | c.300_305del p.L101_D102del | In Frame Del (DEL) | VAF 50/258 reads (19%) | called by mutect2, pindel, varscan2
- USP40 | c.2238_2253del p.E747Tfs*8 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | called by mutect2, pindel, varscan2
- CGN | c.3153G>A p.E1051= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as COSV54972303; called by muse, mutect2, varscan2
- CLUAP1 | c.771C>T p.D257= | Silent (SNP) | VAF 129/242 reads (53%) | catalogued as rs752823842, COSV58894551; called by muse, mutect2, varscan2
- DNAAF1 | c.1086G>A p.K362= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as rs199746574, COSV57578345; called by muse, mutect2, varscan2
- DNAH10 | c.3081T>A p.P1027= (on ENST00000409039; = p.P966= on NM_207437.3) | Silent (SNP) | VAF 154/278 reads (55%) | catalogued as COSV68998658; called by muse, mutect2, varscan2
- ERC1 | c.3048T>G p.L1016= (on ENST00000360905 / NM_178040.4; = p.L988= on NM_178039.4) | Silent (SNP) | VAF 45/294 reads (15%) | catalogued as COSV61697898; called by muse, mutect2, varscan2
- ERMARD | c.1842G>A p.Q614= | Silent (SNP) | VAF 39/64 reads (61%) | catalogued as COSV100824507; called by muse, mutect2, varscan2
- EXT1 | c.1704G>A p.T568= | Silent (SNP) | VAF 56/163 reads (34%) | catalogued as rs146389596, COSV100983995; called by muse, mutect2, varscan2
- FAM135B | c.1194C>T p.I398= | Silent (SNP) | VAF 128/437 reads (29%) | catalogued as rs764664874, COSV52722893, COSV52732994; called by muse, mutect2, varscan2
- FAM162A | c.243T>C p.D81= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as COSV51659172; called by muse, mutect2, varscan2
- FBN3 | c.1212C>T p.T404= | Silent (SNP) | VAF 69/323 reads (21%) | catalogued as COSV54468148; called by muse, varscan2
- FFAR3 | c.96C>T p.N32= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as rs1326158320, COSV59909468; called by muse, mutect2, varscan2
- GPR132 | c.435G>A p.V145= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV61678252; called by muse, mutect2, varscan2
- GPR83 | c.1209C>A p.T403= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV54720019; called by muse, mutect2, varscan2
- IL3 | c.321C>A p.A107= | Silent (SNP) | VAF 171/536 reads (32%) | catalogued as COSV57309575; called by muse, mutect2, varscan2
- KCNIP4 | c.144G>A p.T48= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as rs368526954, COSV62850148; called by muse, mutect2, varscan2
- KIF4A | c.1506A>G p.P502= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV65544859; called by muse, mutect2
- LMX1A | c.99T>G p.S33= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99671354; called by muse, mutect2, varscan2
- NR4A2 | c.1230G>T p.L410= | Silent (SNP) | VAF 48/167 reads (29%) | catalogued as COSV59894954; called by muse, mutect2, varscan2
- NRXN1 | c.300T>C p.P100= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV101276081; called by muse, mutect2, varscan2
- PAK4 | c.1698G>A p.L566= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV58946206; called by muse, mutect2, varscan2
- PDLIM4 | c.897G>A p.R299= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as COSV53805012; called by muse, mutect2, varscan2
- POLRMT | c.1245G>T p.V415= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV101646084; called by muse, varscan2
- RHAG | c.645T>A p.T215= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as COSV100006206; called by muse, mutect2, varscan2
- SELENON | c.630T>A p.L210= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV62525684; called by muse, mutect2, varscan2
- SLC39A13 | c.1050G>T p.L350= (on ENST00000362021 / NM_001128225.3; = p.L343= on NM_152264.4) | Silent (SNP) | VAF 9/183 reads (5%) | catalogued as COSV100099173; called by muse, mutect2
- SLC7A4 | c.771C>A p.S257= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100298436; called by muse, mutect2, varscan2
- SNX17 | c.796C>T p.L266= | Silent (SNP) | VAF 72/241 reads (30%) | catalogued as COSV52009443; called by muse, mutect2, varscan2
- SPDEF | c.9C>T p.S3= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1020397262, COSV65001219; called by muse, mutect2, varscan2
- STIP1 | c.231A>G p.R77= | Silent (SNP) | VAF 75/425 reads (18%) | catalogued as COSV59440309; called by muse, mutect2, varscan2
- SULF1 | c.2514T>C p.Y838= | Silent (SNP) | VAF 64/149 reads (43%) | catalogued as COSV52686131; called by muse, mutect2, varscan2
- TMED1 | c.249C>A p.V83= | Silent (SNP) | VAF 51/387 reads (13%) | catalogued as COSV53034185, COSV53034919; called by muse, mutect2, varscan2
- TMEM131L | c.765T>G p.V255= | Silent (SNP) | VAF 78/187 reads (42%) | catalogued as COSV53648543; called by muse, mutect2, varscan2
- TTN | c.41298C>T p.D13766= (on ENST00000591111; = p.D6342= on NM_003319.4) | Silent (SNP) | VAF 115/303 reads (38%) | catalogued as rs370808856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UPF1 | c.894C>T p.D298= | Silent (SNP) | VAF 58/199 reads (29%) | catalogued as rs779100457, COSV53196507; called by muse, mutect2, varscan2
- VSIG2 | c.783C>T p.F261= | Silent (SNP) | VAF 77/85 reads (91%) | catalogued as COSV52519144; called by muse, mutect2, varscan2
- ZNF697 | c.159G>A p.P53= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs374154556; called by muse, mutect2, varscan2
- ZSCAN25 | c.438C>T p.G146= | Silent (SNP) | VAF 29/238 reads (12%) | catalogued as rs376411021; called by muse, mutect2, varscan2
- ZZEF1 | c.7821C>G p.L2607= | Silent (SNP) | VAF 140/162 reads (86%) | catalogued as COSV67559270; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 4/48 reads (8%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- SCAF1 | c.-1C>A | 5'UTR (SNP) | VAF 22/73 reads (30%) | catalogued as COSV99881896; called by muse, mutect2, varscan2
- SPG7 | c.1303+4246C>T | Intron (SNP) | VAF 98/211 reads (46%) | catalogued as rs371077773; called by muse, mutect2, varscan2
- TCF7L2 | c.552+49276C>G | Intron (SNP) | VAF 37/92 reads (40%) | catalogued as COSV60509579; called by muse, mutect2, varscan2
- TTN | c.10360+4296T>C | Intron (SNP) | VAF 56/163 reads (34%) | catalogued as COSV60237676; called by muse, mutect2, varscan2
- WNK2 | chr9:93318548 T>A | 3'Flank (SNP) | VAF 14/45 reads (31%) | catalogued as COSV52953892; called by muse, mutect2, varscan2
